TCGA case TCGA-12-0688 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/65a48904-9532-4dfb-8e84-4deef1881197

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Dead; Days to death: 811 days (2.2 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 74.2 years (27,085 days); Year of diagnosis: 1998; Method of diagnosis: Excisional Biopsy; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 25 days; Days to treatment end: 67 days; Treatment dose: 6,000 cGy; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Days to treatment start: 96 days; Days to treatment end: 179 days; Number of cycles: 2; Treatment dose: 110 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Treatment intent type: Adjuvant; Days to treatment start: 215 days; Days to treatment end: 238 days; Number of cycles: 1; Treatment dose: 38 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Treatment intent type: Adjuvant; Days to treatment start: 238 days; Days to treatment end: 353 days; Number of cycles: 3; Treatment dose: 25 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Treatment intent type: Adjuvant; Days to treatment start: 238 days; Days to treatment end: 353 days; Treatment dose: 100 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 501 days (1.4 years); Days to treatment end: 597 days (1.6 years); Number of cycles: 3; Treatment dose: 150 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 605 days (1.7 years); Days to treatment end: 649 days (1.8 years); Number of cycles: 1; Treatment dose: 340 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Initial disease status: Progressive Disease; Days to treatment start: 649 days (1.8 years); Days to treatment end: 734 days (2.0 years); Number of cycles: 3; Treatment dose: 25 mg; Route of administration: Oral.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 74.8 years (27,313 days); Days to diagnosis: 228 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Day 228 (post initial treatment): Progression or recurrence: Yes; Days to progression: 228 days.
- Days to follow up: 734 days (2.0 years); Disease response: With Tumor.
- Days to follow up: 811 days (2.2 years); Disease response: With Tumor.
- Karnofsky performance status: 100; Timepoint: Post Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-12-0688-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.8; Shortest dimension: 0.5.
  Slide TCGA-12-0688-01A-02-BS2: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 20.
  Slide TCGA-12-0688-01A-01-BS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 25; Percent stromal cells: 0.
- Sample TCGA-12-0688-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-12-0688-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: Ccnu.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Pharmaceutical therapy drug name: CPT-11.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: Temozolamide.
- Drug treatment 4: Pharmaceutical therapy drug name: VP-16.
- Drug treatment 6: Pharmaceutical therapy drug name: Tamoxiten.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 811 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 811 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 228 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-12-0688-01A-02D-0333-01): tumor purity 0.8, ploidy 2.03, whole-genome doublings 0.
